Somatic mutation profile of tumor specimen TCGA-NF-A4WX-01A (aliquot TCGA-NF-A4WX-01A-11D-A28R-08) from TCGA case TCGA-NF-A4WX, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IV; Age at diagnosis: 61.3 years (22,407 days).
Specimen TCGA-NF-A4WX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f34fc95d-7f56-4300-85b4-4155b6fb5537.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NF-A4WX-10A (Blood Derived Normal), aliquot TCGA-NF-A4WX-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/336414ee-e173-46f5-bb40-0afde3b24378

The open-access MAF lists 37 somatic variants for this specimen: 27 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 9, Nonsense Mutation 3, Splice Site 3, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 59/93 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL6A6 | c.6593G>A p.R2198Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs202169366; called by muse, mutect2, varscan2
- DHX57 | c.3101G>A p.R1034H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs146225438; called by muse, mutect2, varscan2
- FOXN3 | c.1354G>T p.E452* (on ENST00000261302; = p.E430* on NM_005197.4) | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99725865; called by muse, mutect2, varscan2
- HFE | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 46/102 reads (45%) | catalogued as rs759524388, CM020721; called by muse, mutect2, varscan2
- INTS11 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs200408789; called by muse, mutect2, varscan2
- JHY | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | catalogued as rs780495678, COSV99912641; called by muse, mutect2, varscan2
- MDN1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs866792453; called by muse, mutect2
- MTBP | c.2578C>T p.R860C | Missense Mutation (SNP) | VAF 42/58 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs974620841, COSV100012640; called by muse, mutect2, varscan2
- NWD1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs148848880; called by muse, mutect2, varscan2
- PIDD1 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs765584346; called by muse, mutect2, varscan2
- PLXDC1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs750109112; called by muse, mutect2
- WDR62 | c.2767G>A p.G923R | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs141094124; called by muse, mutect2, varscan2
- BRCA2 | c.7098del p.T2367Lfs*9 | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | called by mutect2, pindel, varscan2
- CX3CR1 | c.695T>G p.L232R | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DHRS4L2 | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 85/492 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- KLHL22 | c.305G>A p.C102Y | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- KYNU | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- LRRC46 | c.225+2T>C p.X75_splice | Splice Site (SNP) | VAF 59/62 reads (95%) | called by muse, mutect2, varscan2
- NCAPH2 | c.266+1G>A p.X89_splice | Splice Site (SNP) | VAF 105/185 reads (57%) | called by muse, varscan2
- RNF43 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 59/60 reads (98%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- SH3GL1 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 39/41 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SPCS3 | c.27C>G p.N9K | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TSNAX | c.368G>T p.G123V | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP49 | c.517del p.R173Gfs*20 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, pindel, varscan2
- VPS13B | c.2824G>T p.G942C | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WAC | c.78+2T>A p.X26_splice | Splice Site (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- DNASE2 | c.492C>T p.F164= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs540721218, COSV52255402; called by muse, mutect2, varscan2
- FOXK2 | c.1659G>T p.P553= | Silent (SNP) | VAF 12/126 reads (10%) | catalogued as rs139592674; called by muse, mutect2
- MARCHF6 | c.1302C>T p.Y434= | Silent (SNP) | VAF 36/64 reads (56%) | called by muse, mutect2, varscan2
- NAT2 | c.528T>A p.L176= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- OR5D14 | c.651C>T p.L217= | Silent (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
- PLA2R1 | c.3459A>G p.T1153= | Silent (SNP) | VAF 18/53 reads (34%) | called by muse, mutect2, varscan2
- PLAC1 | c.207C>T p.H69= | Silent (SNP) | VAF 64/68 reads (94%) | catalogued as rs748886436; called by muse, mutect2, varscan2
- PLIN3 | c.165C>T p.H55= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs769845235, COSV55736678; called by muse, mutect2, varscan2
- SP5 | c.1182C>T p.D394= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs755470815, COSV64623261; called by mutect2, varscan2
- UBTFL2 | n.684del | RNA (DEL) | VAF 9/60 reads (15%) | catalogued as rs776016662; called by mutect2, pindel, varscan2
